Somatic mutation profile of tumor specimen TARGET-20-PASRTP-09A (aliquot TARGET-20-PASRTP-09A-01D) from TARGET case TARGET-20-PASRTP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.8 years (5,389 days).
Specimen TARGET-20-PASRTP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1164aede-70a8-492a-af90-24d5d6d9c9c3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASRTP-14A (Bone Marrow Normal), aliquot TARGET-20-PASRTP-14A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86a05dfa-a10e-40da-96cb-786c51cc1f5d

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.213T>G p.F71L | Missense Mutation (SNP) | VAF 124/286 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1555267558, COSV61005635, COSV61011607; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCATG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 15/45 reads (33%) | catalogued as rs1554138188, COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- WT1 | c.812dup p.V272Gfs*26 | Frame Shift Ins (INS) | VAF 21/64 reads (33%) | called by mutect2, pindel, varscan2
